Somatic mutation profile of tumor specimen MP2PRT-PAPKTA-TMP1-A (aliquot MP2PRT-PAPKTA-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPKTA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.0 years (4,382 days).
Specimen MP2PRT-PAPKTA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c6d26c4-44d4-425b-99e6-af8519c371b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPKTA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPKTA-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bed36dc8-fa9f-49e5-86ea-beda7c0d9689

The open-access MAF lists 25 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 16, Silent 3, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPHS1 | c.2491C>T p.R831C | Missense Mutation (SNP) | VAF 57/366 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs386833915, CM990969, COSV100800027; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.947T>C p.L316P | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs888529036; called by muse, mutect2, varscan2
- CFTR | c.1133delinsCCC p.Q378Pfs*11 | Frame Shift Ins (INS) | VAF 26/168 reads (15%) | catalogued as CM024672, COSV50071248; called by mutect2*, pindel, varscan2*
- COBL | c.3445G>A p.E1149K | Missense Mutation (SNP) | VAF 83/517 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375921623, COSV99471039; called by muse, mutect2, varscan2
- IGFN1 | c.2317G>A p.A773T (on ENST00000295591 / NM_001367841.1; = p.A3230T on NM_001164586.2) | Missense Mutation (SNP) | VAF 168/517 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as rs146376343; called by muse, mutect2, varscan2
- MATN4 | c.236C>G p.S79W | Missense Mutation (SNP) | VAF 98/494 reads (20%) | PolyPhen probably damaging (1); catalogued as COSV59213449; called by muse, mutect2, varscan2
- OR8S1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs139500653; called by muse, mutect2
- SPINK5 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); catalogued as rs374182762; called by muse, mutect2
- ATF7IP | c.2578del p.T860Lfs*50 | Frame Shift Del (DEL) | VAF 69/312 reads (22%) | called by mutect2, pindel, varscan2
- CFTR | c.1132_1133insCC p.Q378Pfs*11 | Frame Shift Ins (INS) | VAF 18/131 reads (14%) | called by mutect2, varscan2
- FLNB | c.2434G>A p.V812M | Missense Mutation (SNP) | VAF 101/322 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGKV1D-43 | chr2:90210514 GTATTATAGTACCCCTCCCACAGTGTTACACACCCAAACAAAAAC>CCCGGGGA | Missense Mutation (DEL) | VAF 57/173 reads (33%) | called by pindel, varscan2*
- MUC12 | c.14249G>C p.S4750T (on ENST00000379442; = p.S4607T on NM_001164462.1) | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.02); called by muse, mutect2
- MYBPC1 | c.2587_2592+4delinsCC p.X863_splice (on ENST00000550270 / NM_206820.2; = p.X870_splice on NM_002465.4) | Splice Site (DEL) | VAF 45/244 reads (18%) | called by pindel, varscan2*
- OR10J5 | c.664T>C p.S222P | Missense Mutation (SNP) | VAF 63/421 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- PATJ | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIWIL1 | c.408T>A p.Y136* | Nonsense Mutation (SNP) | VAF 84/395 reads (21%) | called by muse, mutect2, varscan2
- SETBP1 | c.2818A>T p.R940W | Missense Mutation (SNP) | VAF 99/483 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPEF2 | c.4537C>T p.H1513Y | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- SZT2 | c.9631C>A p.R3211S (on ENST00000634258 / NM_001365999.1; = p.R3154S on NM_015284.4) | Missense Mutation (SNP) | VAF 64/403 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TAPBP | c.1263_1266del p.L422Cfs*57 (on ENST00000426633 / NM_172208.2; = p.L422Cfs*51 on NM_003190.5) | Frame Shift Del (DEL) | VAF 55/424 reads (13%) | called by mutect2, pindel, varscan2
- USP24 | c.3044A>T p.D1015V | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNGA2 | c.975C>T p.I325= | Silent (SNP) | VAF 29/646 reads (4%) | called by muse, mutect2
- NPTX2 | c.1269G>A p.T423= | Silent (SNP) | VAF 48/328 reads (15%) | catalogued as rs748811932; called by muse, mutect2, varscan2
- PCDH15 | c.5406G>A p.T1802= | Silent (SNP) | VAF 45/343 reads (13%) | catalogued as rs534255804, COSV57395101; called by muse, mutect2, varscan2
